Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6WG, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6WG-01A (Primary Tumor).

Histomorphology typical for diffuse astrocytoma with increased mitotic activity. Proliferation index 7%.

Diagnosis

Anaplastic astrocytoma WHO grade III

ICD-O-3

QCLF Astrocytoma, grade III
Site: Brain, supratentorial
9401/3
C71.0
QW 8/12/13

untranslated full report is
housed at the BCR.

Criteria	hw 7/16/13	Inc
ICDAA Discrepancy		✓
Local Synchronous Primary Noted		✓

Source: NCI Genomic Data Commons file edb4323c-237d-42a4-b5fd-31234dde4bd2 (TCGA-S9-A6WG.82E91E98-4371-46DC-912C-6D4B3621601E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).